Somatic mutation profile of tumor specimen 0DVCF2 from CCDI case PBCKDN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdominal esophagus; Age at diagnosis: 2.4 years (863 days).
Specimen 0DVCF2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b15f81c-4d0a-4f1e-b6ef-a14d5018bc21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d682f48-b743-4dd8-9827-92b7c7c23760

The open-access MAF lists 33 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, 3'UTR 3, Nonsense Mutation 2, 5'UTR 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH2 | c.7198C>T p.R2400* | Nonsense Mutation (SNP) | VAF 90/547 reads (16%) | hotspot (GDC flag); catalogued as rs1325403451, CM112315, COSV56682519; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL592490.1 | c.2317G>T p.D773Y | Missense Mutation (SNP) | VAF 316/815 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69426784; called by muse, mutect2, varscan2
- CHRM3 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 384/768 reads (50%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs201042655, COSV55079216; called by muse, mutect2, varscan2
- PRRC2A | c.3776G>A p.R1259K | Missense Mutation (SNP) | VAF 156/362 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as rs769576665; called by muse, mutect2, varscan2
- RBM10 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 144/321 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1556778322; called by muse, mutect2, varscan2
- RHOA | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 38/934 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV104435087; called by muse, mutect2
- ZNF556 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 262/539 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs376991458, COSV56914825; called by muse, mutect2, varscan2
- CEP126 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 268/659 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DSC3 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 197/472 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FGFR4 | c.1652A>C p.E551A | Missense Mutation (SNP) | VAF 290/361 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGFR4 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 210/246 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPR18 | c.84C>G p.F28L | Missense Mutation (SNP) | VAF 138/740 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- JAG1 | c.1492A>G p.N498D | Missense Mutation (SNP) | VAF 118/946 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KCNMB1 | c.537G>C p.K179N | Missense Mutation (SNP) | VAF 145/926 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LALBA | c.369-1G>C p.X123_splice | Splice Site (SNP) | VAF 82/747 reads (11%) | called by muse, mutect2, varscan2
- LRP1B | c.5168G>C p.S1723T | Missense Mutation (SNP) | VAF 270/984 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRRK2 | c.3436G>T p.E1146* | Nonsense Mutation (SNP) | VAF 342/1095 reads (31%) | called by muse, mutect2, varscan2
- PYCR3 | c.699C>G p.D233E | Missense Mutation (SNP) | VAF 386/907 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RYBP | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 250/1029 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- AHNAK2 | c.7101C>T p.S2367= | Silent (SNP) | VAF 90/225 reads (40%) | catalogued as rs753362085, COSV100318347; called by muse, mutect2, varscan2
- AKAP8L | c.66C>T p.S22= | Silent (SNP) | VAF 74/512 reads (14%) | catalogued as rs766188877; called by muse, mutect2, varscan2
- ALS2CL | c.1218C>T p.F406= | Silent (SNP) | VAF 100/509 reads (20%) | catalogued as rs144964538, COSV59672516, COSV59672870; called by muse, mutect2, varscan2
- IRAG2 | c.1995C>A p.I665= | Silent (SNP) | VAF 56/541 reads (10%) | called by muse, mutect2, varscan2
- KLHL15 | c.462A>G p.L154= | Silent (SNP) | VAF 253/711 reads (36%) | catalogued as COSV104406703; called by muse, mutect2, varscan2
- OR10H4 | c.756G>A p.T252= | Silent (SNP) | VAF 111/676 reads (16%) | catalogued as rs778154274, COSV100437730; called by muse, mutect2, varscan2
- SEZ6 | c.2658G>A p.S886= | Silent (SNP) | VAF 276/667 reads (41%) | catalogued as rs759828625; called by muse, mutect2, varscan2
- SLC6A1 | c.114G>A p.A38= | Silent (SNP) | VAF 272/568 reads (48%) | catalogued as rs139224269; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP26 | c.*3G>C | 3'UTR (SNP) | VAF 110/713 reads (15%) | catalogued as rs376395047; called by muse, mutect2, varscan2
- DDX3X | c.-59C>T | 5'UTR (SNP) | VAF 19/121 reads (16%) | catalogued as rs1360890304; called by muse, mutect2, varscan2
- KAZN | c.*93C>T | 3'UTR (SNP) | VAF 53/139 reads (38%) | called by muse, mutect2, varscan2
- PDE6A | c.2274+36G>C | Intron (SNP) | VAF 167/326 reads (51%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 20/176 reads (11%) | called by muse, varscan2
- UBE2J1 | c.*10G>T | 3'UTR (SNP) | VAF 280/699 reads (40%) | called by muse, mutect2, varscan2
